Gene-level copy-number profile of tumor specimen HCM-CSHL-0618-C18-06A from HCMI case HCM-CSHL-0618-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 84.9 years (31,013 days).
Specimen HCM-CSHL-0618-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0640cf7a-9692-475e-b08f-7e0863ad0090.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0618-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/031bf3c2-044c-47ec-be0d-8d776a42c5a7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 508; copy number 1: 714; copy number 2: 8,840; copy number 3: 27,143; copy number 4: 17,175; copy number 5: 4,464; copy number 6: 39.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:57,246,960–57,326,447, 5 genes (within-gene range 0–2): HNRNPA3P11, SNORD13D, LINC00926, LINC01413, NDUFB10P1.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 422. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
